Gene-level copy-number profile of tumor specimen TCGA-EJ-7321-01A from TCGA case TCGA-EJ-7321, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.8 years (21,108 days).
Specimen TCGA-EJ-7321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.d4e45638-6a32-4342-a942-21937718fec5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7321-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e46cdc85-b222-4eb4-9d4c-b1d724a533c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 686; copy number 1: 5,075; copy number 2: 53,971; copy number 3: 87.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7321-01A-31D-2259-01): tumor purity 0.41, ploidy 3.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 686 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:6,403,551–14,023,422, 297 genes (broad region; genes not listed).
- chr8:14,161,084–14,165,359, 1 gene: AC022039.1.
- chr8:18,527,303–29,957,348, 236 genes (within-gene range 0–1) (broad region; genes not listed).
- chr17:7,281,718–8,210,600, 91 genes (broad region; genes not listed).
- chr21:38,380,027–41,531,116, 61 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
